Somatic mutation profile of tumor specimen TCGA-98-8023-01A (aliquot TCGA-98-8023-01A-11D-2244-08) from TCGA case TCGA-98-8023, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 70.5 years (25,732 days).
Specimen TCGA-98-8023-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b745bda-d6ec-4a81-a474-5b0dd13d8c7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-98-8023-10A (Blood Derived Normal), aliquot TCGA-98-8023-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/359244b5-e5f2-404c-a4a6-52bc485c5ae7

The open-access MAF lists 221 somatic variants for this specimen: 158 protein-altering or splice-affecting, 53 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 53, Nonsense Mutation 10, Frame Shift Del 5, Intron 4, Splice Site 3, 3'UTR 2, 5'UTR 2, 5'Flank 2, In Frame Del 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACRBP | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99976056; called by muse, mutect2
- ACTC1 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV99291769; called by muse, mutect2, varscan2
- ADCY9 | c.3641G>T p.R1214L | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.392); catalogued as COSV99569748; called by muse, mutect2, varscan2
- ADGRB3 | c.1235G>T p.C412F | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV101000290; called by muse, mutect2, varscan2
- ADGRG4 | c.8814C>A p.D2938E | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV54968786; called by muse, mutect2, varscan2
- AMPD2 | c.444G>C p.E148D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as COSV99857599; called by muse, mutect2, varscan2
- ANKH | c.443A>G p.H148R | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV99414830; called by muse, mutect2, varscan2
- APP | c.1575G>T p.Q525H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100695585; called by muse, mutect2, varscan2
- ATP2A2 | c.2444T>A p.I815N | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100428529; called by muse, mutect2, varscan2
- AVPR1A | c.532A>G p.S178G | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1398515623, COSV100146823; called by muse, mutect2, varscan2
- BAIAP3 | c.3061G>T p.E1021* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as rs760205376, COSV50103879, COSV99136177; called by muse, mutect2, varscan2
- BIRC6 | c.12625C>T p.L4209F | Missense Mutation (SNP) | VAF 52/383 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101428115; called by muse, mutect2, varscan2
- BMP5 | c.710C>A p.T237K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.142); catalogued as COSV100895880; called by muse, mutect2, varscan2
- BRINP3 | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs149389696; called by muse, mutect2, varscan2
- BRINP3 | c.1515C>A p.D505E | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs758474926, COSV100818336, COSV100818640; called by muse, mutect2, varscan2
- C8orf34 | c.1083A>C p.E361D | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.775); catalogued as rs1393535967, COSV100445682; called by muse, mutect2, varscan2
- CAAP1 | c.929A>C p.E310A | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.302); catalogued as COSV100445101; called by muse, mutect2, varscan2
- CAND1 | c.438A>T p.E146D | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV101598268; called by muse, mutect2, varscan2
- CCDC39 | c.1834T>A p.S612T | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV99868270; called by muse, mutect2, varscan2
- CD5 | c.139C>A p.Q47K | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.301); catalogued as COSV100759789; called by muse, mutect2, varscan2
- CDC42BPA | c.3558G>T p.E1186D (on ENST00000334218 / NM_001366019.2; = p.E1173D on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/322 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV100504537; called by muse, mutect2, varscan2
- CDCA2 | c.3056G>C p.G1019A | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.359); catalogued as COSV100398824; called by muse, mutect2, varscan2
- CDH2 | c.1942A>G p.I648V | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52271679; called by muse, mutect2, varscan2
- CELF4 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100611455; called by muse, mutect2, varscan2
- CHIT1 | c.1068G>A p.M356I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV99705186; called by muse, mutect2, varscan2
- CHIT1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99705188; called by muse, mutect2, varscan2
- CHODL | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV100166745; called by mutect2, varscan2
- CHRNA1 | c.1105A>G p.M369V (on ENST00000261007 / NM_001039523.3; = p.M344V on NM_000079.4) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV53681960; called by muse, mutect2, varscan2
- CLHC1 | c.1309A>C p.I437L | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101284871; called by muse, mutect2, varscan2
- CLVS1 | c.73C>A p.H25N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as COSV100369765; called by muse, mutect2, varscan2
- CNTNAP4 | c.2777G>T p.R926I | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100270587; called by muse, mutect2, varscan2
- CNTNAP5 | c.1589A>T p.Q530L | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV101443348, COSV70495623; called by muse, mutect2, varscan2
- COL22A1 | c.3741A>T p.R1247S | Missense Mutation (SNP) | VAF 76/331 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.966); catalogued as COSV100277658; called by muse, mutect2, varscan2
- COL4A6 | c.2062G>T p.G688C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57858652, COSV57872087; called by muse, mutect2, varscan2
- CYP2J2 | c.1393C>G p.L465V | Missense Mutation (SNP) | VAF 71/265 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV100967987; called by muse, mutect2, varscan2
- DCLK3 | c.1071G>T p.E357D | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV101373945; called by muse, mutect2, varscan2
- DLG2 | c.1609C>G p.R537G | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV54631130, COSV99714552; called by muse, mutect2, varscan2
- DNAH5 | c.6892G>A p.A2298T | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54260089; called by muse, mutect2, varscan2
- DNER | c.1663G>C p.G555R | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV59161849, COSV59168801; called by muse, mutect2, varscan2
- ENPP1 | c.2369G>T p.G790V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100719483, COSV62933807; called by muse, mutect2, varscan2
- ETFRF1 | c.181T>C p.F61L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV100334423; called by muse, mutect2, varscan2
- EXOSC4 | c.333C>G p.I111M | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100284024; called by muse, mutect2
- FAM234B | c.1012G>C p.A338P | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99545572; called by muse, mutect2, varscan2
- FAM83B | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.158); catalogued as COSV60920056; called by muse, mutect2, varscan2
- FAM83B | c.2260G>C p.E754Q | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.203); catalogued as COSV100174295; called by muse, mutect2
- FAM83C | c.1712G>A p.G571D | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs766057483, COSV100981548; called by muse, mutect2, varscan2
- FAM83C | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777525868, COSV100981546; called by muse, varscan2
- FLG | c.4766G>T p.R1589L | Missense Mutation (SNP) | VAF 63/480 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as rs143520776, COSV100911423; called by muse, mutect2, varscan2
- FMN2 | c.2609T>C p.M870T | Missense Mutation (SNP) | VAF 57/240 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1425967506, COSV100144461; called by muse, mutect2, varscan2
- FMNL1 | c.1167G>T p.E389D | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); catalogued as COSV100056375; called by muse, mutect2, varscan2
- GABRR3 | c.881G>T p.R294I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs766474256, COSV101512276; called by muse, mutect2, varscan2
- GIGYF2 | c.3137G>C p.W1046S | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101004233, COSV65252040; called by muse, mutect2, varscan2
- GK2 | c.866C>A p.T289K | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100725918, COSV62626635; called by muse, mutect2, varscan2
- GOLGA5 | c.2116-1G>T p.X706_splice | Splice Site (SNP) | VAF 6/39 reads (15%) | catalogued as COSV99370843; called by muse, mutect2, varscan2
- GPAM | c.1531G>T p.V511L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs772930204, COSV100788166; called by muse, mutect2, varscan2
- HBG2 | c.315+1G>A p.X105_splice | Splice Site (SNP) | VAF 27/141 reads (19%) | catalogued as COSV100400608, COSV100400648; called by muse, mutect2, varscan2
- HSF5 | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV100050945; called by muse, mutect2, varscan2
- IGF2R | c.7053C>A p.Y2351* | Nonsense Mutation (SNP) | VAF 20/62 reads (32%) | catalogued as COSV100806763, COSV100807197; called by muse, mutect2, varscan2
- IGFBP3 | c.557A>G p.Y186C | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV99298295; called by muse, mutect2, varscan2
- KAT14 | c.439A>T p.R147W | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100890053; called by muse, mutect2
- KCNH2 | c.2596A>C p.N866H | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV100059699; called by muse, mutect2
- KCNH6 | c.1228C>T p.L410F | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100120939, COSV59005076; called by muse, mutect2, varscan2
- KDM4D | c.187T>C p.Y63H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100624210; called by muse, mutect2, varscan2
- KIF21B | c.3179G>C p.G1060A | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.293); catalogued as COSV100144289; called by muse, mutect2
- KRTAP13-1 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.515); catalogued as rs1359186304, COSV100819865, COSV62663087, COSV62663667; called by muse, mutect2, varscan2
- LGSN | c.293T>G p.V98G | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101040440; called by muse, mutect2, varscan2
- LHCGR | c.1033C>G p.P345A | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV54294436, COSV99683479; called by muse, mutect2
- LIMK2 | c.1262A>C p.D421A | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV100058298; called by muse, mutect2, varscan2
- LMOD2 | c.5C>A p.S2Y | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101505436, COSV71755910; called by muse, mutect2
- LRRC37B | c.524T>G p.L175R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100496178; called by muse, mutect2, varscan2
- MAGEE1 | c.1800G>T p.E600D | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99058314; called by muse, mutect2, varscan2
- MDH1B | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV100982165; called by muse, mutect2, varscan2
- MPHOSPH10 | c.18G>T p.W6C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.439); catalogued as COSV99731071; called by muse, mutect2
- MUC17 | c.12315C>A p.F4105L | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV100072684, COSV60282357; called by muse, mutect2
- NBEAL2 | c.5314G>C p.E1772Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.421); catalogued as COSV99435568; called by muse, varscan2
- NEK10 | c.764T>C p.L255P | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100411679; called by muse, mutect2, varscan2
- NFATC2 | c.1977C>A p.Y659* | Nonsense Mutation (SNP) | VAF 24/212 reads (11%) | catalogued as COSV101043914; called by muse, mutect2, varscan2
- NLGN4X | c.1021G>C p.G341R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52006855, COSV99319329, COSV99321108; called by muse, mutect2, varscan2
- NOS1 | c.44T>C p.V15A | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.42); catalogued as COSV100500374; called by muse, mutect2, varscan2
- NRXN1 | c.1200C>A p.Y400* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100454382; called by muse, varscan2
- NUP205 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 8/79 reads (10%) | catalogued as COSV99606795; called by muse, mutect2, varscan2
- OAF | c.704G>T p.R235L | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100202911, COSV100202999; called by muse, mutect2, varscan2
- OR2L2 | c.103del p.L35* | Frame Shift Del (DEL) | VAF 51/230 reads (22%) | catalogued as COSV100823655, COSV63552249; called by mutect2, pindel, varscan2
- OR2L2 | c.604A>T p.S202C | Missense Mutation (SNP) | VAF 36/283 reads (13%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.778); catalogued as COSV100823408; called by muse, mutect2, varscan2
- OR2T33 | c.339A>T p.L113F | Missense Mutation (SNP) | VAF 13/274 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100531533, COSV100531784; called by muse, mutect2
- OR4C12 | c.662G>C p.R221T | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.015); catalogued as COSV100078423; called by muse, mutect2, varscan2
- OR51B5 | c.173A>G p.Y58C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100332504; called by muse, mutect2, varscan2
- OR5AS1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV57981163; called by muse, mutect2, varscan2
- OR5W2 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100747582; called by muse, mutect2, varscan2
- OR7C1 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs200940777, COSV50183412; called by muse, mutect2, varscan2
- PAPSS1 | c.641A>T p.Q214L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs748535214, COSV99491956; called by muse, mutect2, varscan2
- PCDH10 | c.1692A>G p.I564M | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs773122619, COSV99993345; called by muse, mutect2, varscan2
- PCDH19 | c.2925C>A p.N975K (on ENST00000373034 / NM_001184880.2; = p.N927K on NM_020766.3) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV99719501; called by muse, mutect2, varscan2
- PCDHB12 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.023); catalogued as COSV99507102; called by muse, mutect2, varscan2
- PI4KA | c.2262G>T p.K754N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as COSV99745512; called by muse, mutect2, varscan2
- PIP5K1B | c.813G>T p.L271F | Missense Mutation (SNP) | VAF 53/264 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV99598532; called by muse, mutect2, varscan2
- PIP5K1B | c.814G>T p.G272* | Nonsense Mutation (SNP) | VAF 51/263 reads (19%) | catalogued as COSV99598534; called by muse, mutect2, varscan2
- PIWIL1 | c.1581A>T p.R527S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV99806245; called by muse, mutect2, varscan2
- PKHD1 | c.10079G>A p.R3360K | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as COSV100582458; called by muse, mutect2, varscan2
- PKHD1L1 | c.1886A>T p.K629I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV101005938; called by muse, mutect2, varscan2
- PLXNB2 | c.618C>A p.Y206* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as rs780711806, COSV100833987; called by muse, mutect2, varscan2
- PPP1R16B | c.271A>G p.K91E | Missense Mutation (SNP) | VAF 64/293 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV100239253; called by muse, mutect2, varscan2
- PRUNE2 | c.2861T>G p.L954R | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV100944432; called by muse, mutect2, varscan2
- PSMA2 | c.474G>A p.W158* | Nonsense Mutation (SNP) | VAF 9/107 reads (8%) | catalogued as COSV99785787; called by muse, mutect2
- PSMB5 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 16/192 reads (8%) | catalogued as COSV100557318; called by muse, mutect2
- QARS1 | c.860A>G p.N287S | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100069938; called by muse, mutect2, varscan2
- RADIL | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs200059500; called by muse, varscan2
- RUNX1T1 | c.417C>A p.D139E (on ENST00000265814 / NM_001198628.1; = p.D112E on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV56157486; called by muse, mutect2, varscan2
- RYR3 | c.2506G>T p.D836Y | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV66810251; called by muse, mutect2, varscan2
- SAMD3 | c.781G>T p.A261S | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV100931723; called by muse, mutect2, varscan2
- SAMD9 | c.4616T>C p.L1539S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs759469955, COSV101180187; called by muse, mutect2, varscan2
- SCLT1 | c.956G>T p.C319F | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.429); catalogued as COSV99827606; called by muse, mutect2, varscan2
- SCN9A | c.256A>C p.K86Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV100312264; called by muse, mutect2, varscan2
- SEMA3E | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as COSV100318120; called by muse, mutect2, varscan2
- SEMA7A | c.804G>A p.G268= | Splice Region (SNP) | VAF 12/85 reads (14%) | catalogued as COSV56090355; called by muse, mutect2, varscan2
- SERPINI1 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285351113, COSV99854970; called by muse, mutect2, varscan2
- SLC44A5 | c.251C>A p.T84N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV100901736; called by muse, mutect2, varscan2
- SOGA3 | c.1744A>T p.T582S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.759); catalogued as COSV100846868; called by muse, mutect2, varscan2
- SPON1 | c.683C>A p.A228D | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV100115632; called by muse, mutect2, varscan2
- STAR | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99378993; called by muse, mutect2, varscan2
- STARD13 | c.554G>T p.S185I (on ENST00000336934 / NM_001243476.3; = p.S67I on NM_052851.3) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV99715699; called by muse, mutect2, varscan2
- STK31 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.018); catalogued as rs1369485527, COSV100669286, COSV63453958; called by muse, mutect2, varscan2
- STX1B | c.242T>G p.I81S | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99288045; called by muse, mutect2, varscan2
- SVEP1 | c.5105C>A p.S1702* | Nonsense Mutation (SNP) | VAF 38/140 reads (27%) | catalogued as COSV99928797; called by muse, mutect2, varscan2
- SYCP1 | c.2204A>T p.Y735F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV101050873; called by muse, mutect2, varscan2
- SYT9 | c.965T>C p.V322A | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV100607914; called by muse, mutect2, varscan2
- TAZ | c.239-2A>G p.X80_splice | Splice Site (SNP) | VAF 17/43 reads (40%) | catalogued as COSV99185880; called by muse, mutect2, varscan2
- TBCCD1 | c.1130A>T p.N377I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV100111920; called by muse, mutect2, varscan2
- TENM3 | c.941C>G p.A314G | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV101305017, COSV69303779; called by muse, mutect2, varscan2
- THUMPD2 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99572080; called by muse, mutect2, varscan2
- TLN2 | c.3334G>T p.A1112S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.407); catalogued as rs141890260, COSV60896236; called by muse, mutect2, varscan2
- TRIM50 | c.862A>G p.K288E | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as COSV100297031; called by muse, mutect2
- TRMT2B | c.1323G>C p.R441S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV58620320; called by muse, mutect2, varscan2
- TSPYL5 | c.107C>G p.P36R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100438960; called by muse, mutect2, varscan2
- TTLL2 | c.573C>A p.F191L | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.595); catalogued as COSV53442833, COSV53443027; called by muse, mutect2, varscan2
- TTN | c.46200T>A p.N15400K (on ENST00000591111; = p.N7976K on NM_003319.4) | Missense Mutation (SNP) | VAF 17/173 reads (10%) | PolyPhen benign (0.017); catalogued as COSV100605008; called by muse, mutect2
- UGGT2 | c.1417G>C p.G473R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100948596; called by muse, mutect2, varscan2
- UGT1A7 | c.517T>G p.F173V | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs749559644, COSV60850771; called by muse, mutect2, varscan2
- URI1 | c.1217G>T p.R406L | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100368949; called by muse, mutect2, varscan2
- USH2A | c.5519G>A p.G1840E | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM088099, COSV100232718; called by muse, mutect2, varscan2
- USH2A | c.2852G>T p.C951F | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100232719; called by muse, mutect2, varscan2
- VIPR2 | c.655T>C p.W219R | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100056965; called by muse, mutect2, varscan2
- WDFY3 | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55705255; called by muse, mutect2, varscan2
- XKR7 | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.269); catalogued as rs538702175, COSV73813171, COSV73813507; called by muse, mutect2, varscan2
- XKR9 | c.71T>A p.V24E | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV101281888; called by muse, mutect2, varscan2
- ZNF616 | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV100348262; called by muse, mutect2, varscan2
- ADH1C | c.625_627del p.V209del | In Frame Del (DEL) | VAF 93/339 reads (27%) | called by pindel, varscan2
- IGKV1-12 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- KCNA5 | c.1186del p.L396Wfs*36 | Frame Shift Del (DEL) | VAF 15/130 reads (12%) | called by mutect2, varscan2
- LAMB4 | c.745C>A p.L249I | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.158); called by muse, mutect2
- LMO7 | c.4844_4845del p.E1615Vfs*12 (on ENST00000357063; = p.E1296Vfs*12 on NM_005358.5) | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- PEG3 | c.871del p.T291Lfs*23 | Frame Shift Del (DEL) | VAF 10/99 reads (10%) | called by mutect2, pindel
- PLAAT5 | c.82C>G p.R28G | Missense Mutation (SNP) | VAF 2/12 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.238); called by muse, mutect2
- TLR4 | c.693_705del p.T232Ifs*5 (on ENST00000355622 / NM_138554.5; = p.T192Ifs*5 on NM_003266.4) | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | called by mutect2, pindel, varscan2
- TRAV13-2 | c.248C>T p.T83I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TUBGCP5 | c.2874G>C p.L958F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- XKR3 | c.1248G>T p.Q416H | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.265); called by muse, mutect2
- ABCA13 | c.13011G>C p.L4337= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1188976876, COSV101291287; called by muse, mutect2, varscan2
- ACP7 | c.282C>T p.H94= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100488482; called by muse, mutect2, varscan2
- C3orf38 | c.693G>A p.L231= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as COSV100007374; called by muse, mutect2, varscan2
- C7 | c.1806A>T p.G602= | Silent (SNP) | VAF 21/147 reads (14%) | catalogued as COSV100495677; called by muse, mutect2, varscan2
- CTNNA1 | c.1641C>T p.G547= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100242511; called by muse, mutect2, varscan2
- CTNNA2 | c.807C>A p.G269= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV100783169; called by muse, mutect2, varscan2
- CXCR1 | c.924C>A p.I308= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as rs368619392, COSV99826299; called by muse, mutect2, varscan2
- DCLRE1B | c.1278G>T p.T426= | Silent (SNP) | VAF 87/325 reads (27%) | catalogued as COSV100849773, COSV100849781; called by muse, mutect2, varscan2
- DNAH10 | c.8085A>G p.A2695= (on ENST00000409039; = p.A2634= on NM_207437.3) | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV101292160; called by muse, mutect2, varscan2
- DYNC2I1 | c.2523T>C p.S841= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV101337649; called by muse, mutect2, varscan2
- EZH2 | c.564T>C p.D188= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100235375; called by muse, mutect2, varscan2
- FBXL6 | c.1446C>T p.G482= | Silent (SNP) | VAF 28/128 reads (22%) | catalogued as rs782585910, COSV100095635; called by muse, mutect2, varscan2
- FGG | c.270C>A p.I90= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV100271810; called by muse, mutect2, varscan2
- FOXM1 | c.1140T>C p.P380= | Silent (SNP) | VAF 22/137 reads (16%) | catalogued as COSV100700833; called by muse, mutect2, varscan2
- H1-3 | c.624G>A p.P208= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs376819157, COSV99768711; called by muse, mutect2, varscan2
- INHBA | c.552C>A p.G184= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV99637483; called by muse, mutect2, varscan2
- KLHL1 | c.708T>C p.Y236= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV64785774; called by muse, mutect2, varscan2
- LIM2 | c.366C>A p.V122= (on ENST00000596399 / NM_001161748.2; = p.V164= on NM_030657.4) | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as COSV99702315; called by muse, mutect2
- LTBP1 | c.1782C>T p.C594= (on ENST00000404816 / NM_206943.4; = p.C268= on NM_000627.4) | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100616832; called by muse, mutect2, varscan2
- MLIP | c.471A>T p.A157= | Silent (SNP) | VAF 21/150 reads (14%) | catalogued as COSV51438381; called by muse, mutect2
- MORN1 | c.618C>T p.I206= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV101045857; called by muse, mutect2
- MTUS2 | c.1788G>A p.G596= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV70921985; called by muse, mutect2, varscan2
- MUC17 | c.10485C>T p.T3495= | Silent (SNP) | VAF 106/475 reads (22%) | catalogued as COSV100072683, COSV60286810; called by muse, mutect2, varscan2
- MYLIP | c.1257C>G p.P419= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100785934, COSV100785946; called by muse, mutect2, varscan2
- NLRP3 | c.996C>T p.S332= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV100275750; called by muse, mutect2
- OR5L1 | c.678G>A p.L226= | Silent (SNP) | VAF 25/128 reads (20%) | catalogued as COSV61735397; called by muse, mutect2, varscan2
- OR8H2 | c.675C>A p.I225= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV100542256; called by muse, mutect2
- PAPPA2 | c.2520C>T p.S840= | Silent (SNP) | VAF 30/313 reads (10%) | catalogued as COSV100866714; called by muse, mutect2, varscan2
- PCDHB15 | c.1314C>A p.T438= | Silent (SNP) | VAF 57/238 reads (24%) | catalogued as rs782630330, COSV99178806, COSV99178880; called by muse, mutect2, varscan2
- PCDHB4 | c.2058C>A p.T686= | Silent (SNP) | VAF 53/200 reads (27%) | catalogued as COSV52023024, COSV52023509; called by muse, mutect2, varscan2
- PDZD2 | c.2052C>A p.P684= | Silent (SNP) | VAF 11/115 reads (10%) | catalogued as COSV56878683; called by muse, mutect2
- PIK3C2B | c.3006A>G p.K1002= | Silent (SNP) | VAF 20/189 reads (11%) | catalogued as COSV100916056; called by muse, mutect2, varscan2
- PKHD1 | c.3753C>A p.T1251= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV100582460; called by muse, mutect2, varscan2
- PXDN | c.2472C>T p.F824= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV53245328; called by muse, mutect2
- RBL2 | c.2913A>T p.S971= | Silent (SNP) | VAF 45/164 reads (27%) | catalogued as COSV100043518; called by muse, mutect2, varscan2
- RUNDC3B | c.1407C>A p.G469= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV100353637; called by muse, mutect2, varscan2
- RYR2 | c.13107G>T p.L4369= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100769405; called by muse, mutect2, varscan2
- SATB2 | c.288G>C p.L96= | Silent (SNP) | VAF 36/151 reads (24%) | catalogued as COSV99610992; called by muse, mutect2, varscan2
- SCPEP1 | c.945C>T p.G315= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV99227771; called by muse, mutect2, varscan2
- SEPTIN6 | c.699G>T p.L233= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100595534; called by muse, mutect2, varscan2
- SIM1 | c.105G>C p.S35= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV99492225; called by muse, mutect2, varscan2
- SIX4 | c.2026T>C p.L676= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs766811481, COSV99382167; called by muse, mutect2, varscan2
- SLC17A2 | c.237A>G p.T79= | Silent (SNP) | VAF 34/121 reads (28%) | catalogued as rs1441484058, COSV99614138; called by muse, mutect2, varscan2
- SLC37A3 | c.1455A>T p.L485= (on ENST00000326232 / NM_001363375.1; = p.K385* on NM_032295.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 41/150 reads (27%) | catalogued as COSV100405398; called by muse, mutect2, varscan2
- SSH2 | c.2853T>C p.N951= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as rs1340125598, COSV99281812; called by muse, mutect2, varscan2
- TAS2R19 | c.741A>T p.T247= | Silent (SNP) | VAF 38/127 reads (30%) | catalogued as COSV101114601; called by muse, varscan2
- TLK1 | c.2040A>G p.Q680= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV100687951; called by muse, mutect2, varscan2
- TRABD2A | c.600G>A p.R200= | Silent (SNP) | VAF 42/316 reads (13%) | catalogued as COSV100119795; called by muse, mutect2, varscan2
- USH2A | c.2748C>T p.I916= | Silent (SNP) | VAF 36/242 reads (15%) | catalogued as COSV100232722, COSV56379026; called by muse, mutect2, varscan2
- VNN3 | c.480A>G p.Q160= | Silent (SNP) | VAF 62/175 reads (35%) | catalogued as rs1436856838, COSV99258206; called by muse, mutect2, varscan2
- YARS2 | c.606G>A p.Q202= | Silent (SNP) | VAF 10/186 reads (5%) | catalogued as COSV100256368; called by muse, mutect2
- ZBTB4 | c.2856A>T p.L952= | Silent (SNP) | VAF 144/402 reads (36%) | catalogued as COSV100043497; called by muse, mutect2, varscan2
- ZNF416 | c.867G>T p.R289= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV99543747; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73833278 G>A | 5'Flank (SNP) | VAF 9/40 reads (23%) | catalogued as rs771180540; called by muse, varscan2
- AP000769.5 | chr11:65501110 ins AA | 5'Flank (INS) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- ATRIP | c.*2047G>T | 3'UTR (SNP) | VAF 20/63 reads (32%) | catalogued as COSV99603971; called by muse, mutect2, varscan2
- FOLR2 | c.-40A>G | 5'UTR (SNP) | VAF 19/66 reads (29%) | catalogued as COSV99995435; called by muse, mutect2, varscan2
- IL36B | c.261+907T>C | Intron (SNP) | VAF 10/64 reads (16%) | catalogued as COSV99382631; called by muse, mutect2, varscan2
- MACF1 | c.15832-8016A>C | Intron (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99243287; called by muse, varscan2
- PFKL | c.86-815G>A | Intron (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100827099; called by muse, mutect2, varscan2
- SNTG1 | c.-1C>A | 5'UTR (SNP) | VAF 9/43 reads (21%) | catalogued as rs1361909742, COSV99382931; called by muse, mutect2, varscan2
- TMEM71 | c.814+134T>A | Intron (SNP) | VAF 4/57 reads (7%) | catalogued as COSV100785572; called by muse, mutect2
- TRIM10 | c.*196A>C | 3'UTR (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100939674; called by muse, mutect2, varscan2
